Somatic mutation profile of tumor specimen TCGA-B5-A0K9-01A (aliquot TCGA-B5-A0K9-01A-21D-A10O-09) from TCGA case TCGA-B5-A0K9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 88.4 years (32,289 days).
Specimen TCGA-B5-A0K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fb3e23a-e6e7-478d-97f1-a14a1e9c6b8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K9-10A (Blood Derived Normal), aliquot TCGA-B5-A0K9-10A-02D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d179b5ae-48e6-4831-a9e5-9730bd164fc1

The open-access MAF lists 927 somatic variants for this specimen: 715 protein-altering or splice-affecting, 197 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 472, Silent 197, Frame Shift Del 148, Frame Shift Ins 40, Nonsense Mutation 23, Splice Site 17, In Frame Del 12, Intron 8, RNA 4, Splice Region 3, 3'UTR 2, 3'Flank 1.

Variants (750 of 927; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.2412del p.E805Kfs*58 | Frame Shift Del (DEL) | VAF 54/205 reads (26%) | catalogued as rs886039902; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C19orf12 | c.199dup p.A67Gfs*16 (on ENST00000392278 / NM_001031726.3; = p.A56Gfs*16 on NM_031448.6) | Frame Shift Ins (INS) | VAF 44/162 reads (27%) | catalogued as rs398122409; ClinVar: pathogenic; called by mutect2, varscan2
- MYL1 | c.479-2A>G p.X160_splice | Splice Site (SNP) | VAF 99/488 reads (20%) | catalogued as rs1559659233, COSV58974603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 60/230 reads (26%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1709_1735del p.L570_D578del (on ENST00000521381 / NM_181523.3; = p.L300_D308del on NM_181504.4) | In Frame Del (DEL) | VAF 98/471 reads (21%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 178/318 reads (56%) | catalogued as rs786204934, CM110145, COSV64289396, COSV64297896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.1251_1252del p.R418Sfs*9 | Frame Shift Del (DEL) | VAF 41/334 reads (12%) | catalogued as rs1131690889; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZEB1 | c.1576dup p.V526Gfs*3 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | catalogued as rs766305306; ClinVar: pathogenic; called by mutect2, varscan2
- AAK1 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV68642789; called by muse, mutect2, varscan2
- AARS1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV55746724; called by muse, mutect2, varscan2
- ABCA12 | c.5878C>T p.R1960* (on ENST00000272895 / NM_173076.3; = p.R1642* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 164/723 reads (23%) | catalogued as rs769753487, COSV55953399, COSV99790255; called by muse, mutect2, varscan2
- ABCA2 | c.2842C>T p.H948Y (on ENST00000614293; = p.H918Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs1296525189, COSV55799353; called by muse, mutect2, varscan2
- ABCB11 | c.3795A>T p.R1265S | Missense Mutation (SNP) | VAF 19/460 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV55587738; called by muse, mutect2
- ABCB5 | c.1563del p.G522Efs*4 (on ENST00000404938 / NM_001163941.2; = p.G77Efs*4 on NM_178559.6) | Frame Shift Del (DEL) | VAF 108/365 reads (30%) | catalogued as rs780510782, COSV51718286; called by mutect2, pindel, varscan2
- ABCB6 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436080788, COSV54693869, COSV54694307; called by muse, mutect2, varscan2
- ABCB8 | c.1763C>T p.A588V (on ENST00000297504 / NM_001282291.2; = p.A571V on NM_007188.5) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780004246, COSV52503257; called by muse, mutect2, varscan2
- ABHD16B | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as rs1318759533, COSV53861989; called by muse, varscan2
- ABTB2 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs1345996004, COSV54385902; called by muse, mutect2, varscan2
- AC245033.1 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 222/777 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.463); catalogued as rs1227643048; called by muse, mutect2, varscan2
- ACO2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs1301732484, COSV53442012; called by muse, mutect2, varscan2
- ACTC1 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV51758248; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 69/404 reads (17%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAMTSL1 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs778869300, COSV65876775, COSV65876864; called by muse, mutect2, varscan2
- ADCY1 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1326557048, COSV52032152; called by muse, mutect2
- ADCY2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769674129, COSV57864636; called by muse, mutect2, varscan2
- ADCY4 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53474630, COSV99352883; called by muse, mutect2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.536T>C p.L179S | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51561339; called by muse, varscan2
- ADGRB1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV60093822; called by muse, mutect2
- ADRA2A | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447519480, COSV54527297; called by muse, mutect2, varscan2
- AFMID | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59975635; called by muse, mutect2, varscan2
- AGAP3 | c.2599G>T p.E867* (on ENST00000622464; = p.E903* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV52546957; called by muse, mutect2
- AGFG1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59511037; called by muse, mutect2, varscan2
- AKAP17A | c.944A>C p.E315A | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV58308931; called by muse, mutect2, varscan2
- AKAP8 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV54101754; called by muse, mutect2, varscan2
- ALPI | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV55013998; called by muse, mutect2, varscan2
- ALPK3 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.069); catalogued as rs756803744, COSV51929519; called by muse, mutect2, varscan2
- ANKRD27 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs148333561, COSV60132207; called by muse, mutect2, varscan2
- ANKRD27 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs770976586, COSV60130300; called by muse, mutect2, varscan2
- ANKRD52 | c.3134C>T p.T1045M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1352467677, COSV57282661; called by muse, mutect2, varscan2
- ANO3 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 291/993 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV56785368; called by muse, mutect2, varscan2
- AOC3 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53825336; called by muse, mutect2, varscan2
- AOX1 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs137857697, COSV65980824; called by muse, mutect2, varscan2
- AP1B1 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201912976; called by muse, mutect2, varscan2
- APH1B | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 161/595 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs769750905, COSV56013944; called by muse, mutect2, varscan2
- APOB | c.6134C>T p.A2045V | Missense Mutation (SNP) | VAF 108/461 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs754379217, COSV51922225; called by muse, mutect2, varscan2
- APOBR | c.2210C>A p.A737D (on ENST00000431282; = p.A746D on NM_018690.4) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60489526; called by muse, mutect2, varscan2
- ARHGAP36 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs182540216, COSV52264298; called by muse, mutect2, varscan2
- ARHGEF1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV61526883; called by muse, varscan2
- ARHGEF10 | c.3739G>A p.A1247T (on ENST00000398564; = p.A1222T on NM_014629.4) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs576755623, COSV50644511; called by muse, mutect2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID4A | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 86/329 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as rs142443997; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 69/275 reads (25%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ASAP1 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs201422861; called by muse, mutect2, varscan2
- ASB11 | c.95dup p.L32Ffs*14 | Frame Shift Ins (INS) | VAF 64/243 reads (26%) | catalogued as rs777775669; called by mutect2, varscan2
- ASCC3 | c.1850A>G p.H617R | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1319285328, COSV61227195; called by muse, mutect2
- ASPM | c.8519C>A p.A2840D | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV54127236; called by muse, mutect2, varscan2
- ASTN1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751815220, COSV56064909; called by muse, mutect2, varscan2
- ATG2A | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs1367650503, COSV65966203; called by muse, mutect2, varscan2
- ATG2B | c.3842+1G>A p.X1281_splice | Splice Site (SNP) | VAF 40/173 reads (23%) | catalogued as COSV55889835; called by muse, mutect2, varscan2
- ATG9A | c.2260del p.Q754Sfs*90 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as COSV104372927; called by mutect2, pindel, varscan2
- ATP10A | c.271T>G p.F91V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63515274; called by muse, mutect2, varscan2
- ATP6V1B1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs782443411, COSV52268709; called by muse, mutect2, varscan2
- ATP7A | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 184/601 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV58444143; called by muse, mutect2, varscan2
- ATP7A | c.3659-2A>G p.X1220_splice | Splice Site (SNP) | VAF 87/347 reads (25%) | catalogued as COSV58444156; called by muse, mutect2, varscan2
- ATXN7 | c.2340dup p.T781Hfs*6 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | catalogued as rs779764089; called by mutect2, varscan2
- B3GALNT2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs111541487, COSV64003600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B4GALNT4 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327828, COSV57322317; called by muse, mutect2, varscan2
- B4GALT7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1306108840, COSV50352915; called by muse, mutect2, varscan2
- BCOR | c.4892A>T p.D1631V (on ENST00000378444 / NM_001123385.2; = p.D1597V on NM_017745.6) | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV60703575; called by muse, mutect2, varscan2
- BHLHE40 | c.1048G>C p.V350L | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56575179, COSV56575655; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs755506199; called by mutect2, varscan2
- BRCC3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 122/470 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as rs782698211, COSV57462065; called by muse, mutect2, varscan2
- BRD1 | c.2831C>A p.P944Q (on ENST00000216267 / NM_001349940.1; = p.P1075Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV53455827, COSV99349334; called by muse, mutect2
- BTBD7 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs370370251; called by muse, mutect2, varscan2
- BTF3 | c.400A>G p.I134V (on ENST00000380591 / NM_001037637.1; = p.I90V on NM_001207.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.1); catalogued as COSV60063260; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 123/490 reads (25%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BTNL8 | c.118T>C p.C40R | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51457700; called by muse, mutect2, varscan2
- C10orf53 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV65108597; called by muse, mutect2, varscan2
- C18orf25 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs780674721, COSV56365721; called by muse, mutect2, varscan2
- CACNA1C | c.2342C>T p.T781I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV59705665; called by muse, mutect2, varscan2
- CADPS | c.1986del p.K662Nfs*51 | Frame Shift Del (DEL) | VAF 164/751 reads (22%) | catalogued as COSV51899111; called by mutect2, pindel, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/246 reads (14%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CASC3 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52866817; called by muse, mutect2, varscan2
- CASP10 | c.526dup p.T176Nfs*5 | Frame Shift Ins (INS) | VAF 67/345 reads (19%) | catalogued as rs1275157099; called by mutect2, pindel, varscan2
- CATSPER3 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 164/552 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV50945652; called by muse, mutect2
- CBARP | c.166G>C p.V56L (on ENST00000382477; = p.V62L on NM_152769.3) | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53068234; called by muse, mutect2, varscan2
- CC2D1A | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs919803855, COSV58782062; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 90/318 reads (28%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC88B | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs961976142, COSV57265412; called by muse, mutect2, varscan2
- CCT3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs201507712, COSV55288159; called by muse, mutect2, varscan2
- CCT6B | c.795A>C p.K265N | Missense Mutation (SNP) | VAF 142/415 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100031093, COSV58488345; called by muse, mutect2, varscan2
- CDC25A | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 61/224 reads (27%) | catalogued as COSV56769745; called by muse, mutect2, varscan2
- CDC7 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 26/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52309987; called by muse, mutect2
- CDH4 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs150253018; called by muse, mutect2, varscan2
- CDYL2 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as COSV73653937; called by muse, mutect2, varscan2
- CELF2 | c.7T>C p.C3R | Missense Mutation (SNP) | VAF 232/1035 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.018); catalogued as COSV64928753; called by muse, mutect2, varscan2
- CELSR2 | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54768119, COSV54768843; called by muse, mutect2, varscan2
- CFAP410 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs760073135, COSV57394323; called by muse, mutect2, varscan2
- CFAP65 | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58559203; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 55/180 reads (31%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP74 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs917431326, COSV54564663; called by muse, mutect2
- CFHR5 | c.533dup p.N178Kfs*20 | Frame Shift Ins (INS) | VAF 77/521 reads (15%) | catalogued as rs746586384; called by mutect2, pindel, varscan2
- CHRNA9 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 122/416 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs373239007; called by muse, mutect2, varscan2
- CLASP2 | c.1493A>G p.H498R | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs1196556763, COSV56278705; called by muse, mutect2
- CLBA1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 127/381 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1437142862, COSV66347904; called by muse, mutect2, varscan2
- CLEC18B | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 81/900 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60577070; called by muse, mutect2, varscan2
- CLN8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs775400768, COSV58669944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLTRN | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 118/460 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV66711641; called by muse, mutect2, varscan2
- CNGA2 | c.374+1G>A p.X125_splice | Splice Site (SNP) | VAF 12/278 reads (4%) | catalogued as COSV61703798; called by muse, mutect2
- CNGA3 | c.1510A>C p.S504R | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55623228; called by muse, mutect2, varscan2
- CNPPD1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55406091; called by muse, mutect2, varscan2
- CNTN4 | c.135del p.V46* | Frame Shift Del (DEL) | VAF 106/450 reads (24%) | catalogued as COSV68568603; called by mutect2, pindel, varscan2
- CNTN4 | c.1843C>A p.L615I | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV61870190; called by muse, mutect2, varscan2
- COL11A1 | c.2764G>T p.G922* | Nonsense Mutation (SNP) | VAF 23/171 reads (13%) | catalogued as COSV62177368; called by muse, mutect2, varscan2
- COL4A4 | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61630664; called by muse, mutect2, varscan2
- COL4A6 | c.4999C>T p.P1667S | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV57862013; called by muse, mutect2, varscan2
- COL6A6 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 117/420 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV62021009; called by muse, mutect2, varscan2
- CORIN | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56688720; called by muse, mutect2, varscan2
- COX7B | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV64864537; called by muse, mutect2
- CP | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 149/569 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1286440771, COSV52829767; called by muse, mutect2, varscan2
- CPAMD8 | c.517C>T p.R173W (on ENST00000651564; = p.R126W on NM_015692.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs766632352, COSV52232794; called by muse, mutect2, varscan2
- CPNE1 | c.375del p.T126Pfs*9 (on ENST00000352393; = p.T131Pfs*9 on NM_003915.5) | Frame Shift Del (DEL) | VAF 123/437 reads (28%) | catalogued as COSV58293142; called by mutect2, pindel, varscan2
- CRYBG3 | c.7718C>A p.S2573Y | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV51710600; called by muse, mutect2
- CSNK1G1 | c.1107+2T>C p.X369_splice | Splice Site (SNP) | VAF 18/595 reads (3%) | catalogued as COSV57307839; called by muse, mutect2
- CSTF1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV53858305; called by muse, mutect2
- CTIF | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs139514005; called by muse, mutect2, varscan2
- CUL9 | c.5323C>T p.Q1775* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV52726802; called by muse, mutect2, varscan2
- CUL9 | c.6703C>T p.R2235C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1385216171, COSV52726825; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 99/273 reads (36%) | catalogued as rs745836350; called by mutect2, varscan2
- CYFIP2 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.58); catalogued as COSV59032742; called by muse, mutect2, varscan2
- CYFIP2 | c.3065G>T p.R1022M (on ENST00000616178 / NM_001291722.2; = p.R997M on NM_014376.4) | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100556105, COSV59032769; called by muse, mutect2, varscan2
- CYP2B6 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs374099483; called by muse, mutect2, varscan2
- DCAF17 | c.619A>G p.N207D | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59829913; called by muse, mutect2, varscan2
- DDO | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 139/502 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64469942; called by muse, mutect2, varscan2
- DDX3X | c.320G>A p.G107D (on ENST00000399959; = p.G108D on NM_001356.5) | Missense Mutation (SNP) | VAF 137/504 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV67863266; called by muse, mutect2, varscan2
- DDX42 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 135/423 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753293991, COSV63789170; called by muse, mutect2, varscan2
- DENND4C | c.3304G>A p.A1102T (on ENST00000434457 / NM_001330640.2; = p.A1053T on NM_017925.7) | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as COSV63008546; called by muse, mutect2, varscan2
- DENND6A | c.1696-1G>A p.X566_splice | Splice Site (SNP) | VAF 90/329 reads (27%) | catalogued as COSV60768001; called by muse, mutect2, varscan2
- DEPDC1 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 114/459 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV63957862, COSV63958922; called by muse, mutect2, varscan2
- DGAT2L6 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60717386; called by muse, mutect2
- DGCR6L | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143957631; called by muse, mutect2, varscan2
- DHX32 | c.1979_1981del p.K660del | In Frame Del (DEL) | VAF 70/241 reads (29%) | catalogued as rs751051377; called by pindel, varscan2
- DICER1 | c.4271A>G p.E1424G | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as COSV58617165; called by muse, mutect2
- DIP2C | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs772099485, COSV55151248; called by muse, mutect2, varscan2
- DMRTC2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.984); catalogued as rs781984329, COSV54186179; called by muse, mutect2, varscan2
- DNAH5 | c.11471G>A p.S3824N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54213463; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 41/332 reads (12%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAJA2 | c.899del p.P300Lfs*4 | Frame Shift Del (DEL) | VAF 23/201 reads (11%) | catalogued as COSV57694509; called by mutect2, pindel, varscan2
- DOCK5 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs769071784, COSV52397464; called by muse, mutect2, varscan2
- DOK1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV51206607; called by muse, mutect2, varscan2
- DPF2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748705843, COSV52888318; called by muse, mutect2, varscan2
- DPH6 | c.177C>A p.D59E | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1334637909, COSV56613264; called by muse, mutect2, varscan2
- DPY19L4 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.935); catalogued as COSV68962503; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 54/236 reads (23%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSCAM | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 137/481 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs748635134, COSV68021632; called by muse, mutect2, varscan2
- DUS2 | c.1082+2T>C p.X361_splice | Splice Site (SNP) | VAF 45/202 reads (22%) | catalogued as COSV62708155; called by muse, mutect2, varscan2
- DUSP10 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 110/568 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV60457091; called by muse, mutect2, varscan2
- DYM | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 111/404 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.068); catalogued as rs867765803, COSV53982085; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 62/238 reads (26%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNLRB1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1348426601, COSV55963797; called by muse, mutect2, varscan2
- EFCAB6 | c.1178T>G p.I393S | Missense Mutation (SNP) | VAF 249/879 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV53060349, COSV53073419; called by muse, mutect2, varscan2
- EFCAB7 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV60683318; called by muse, mutect2, varscan2
- EGF | c.2648del p.P883Lfs*67 | Frame Shift Del (DEL) | VAF 87/454 reads (19%) | catalogued as rs758373637; called by mutect2, pindel, varscan2
- EME1 | c.274_276del p.E92del | In Frame Del (DEL) | VAF 30/214 reads (14%) | catalogued as rs753452084; called by pindel, varscan2
- ENOX1 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54892358; called by muse, mutect2, varscan2
- ENPEP | c.347del p.T116Rfs*4 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs1307630732, COSV54448526, COSV99486896; called by mutect2, pindel, varscan2
- EP400 | c.7069G>A p.V2357M | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs141823156; called by muse, mutect2, varscan2
- EPHA4 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 134/565 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV56029159; called by muse, mutect2, varscan2
- EPHX2 | c.1363A>G p.K455E | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs1319220922, COSV66844278; called by muse, mutect2, varscan2
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 100/299 reads (33%) | catalogued as rs760182064; called by mutect2, varscan2
- EXOC1 | c.2336A>G p.N779S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV62119616; called by muse, mutect2, varscan2
- EXOSC9 | c.234T>A p.F78L | Missense Mutation (SNP) | VAF 119/395 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.201); catalogued as COSV54664801, COSV54665399; called by muse, mutect2, varscan2
- FAAH | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV54543545, COSV99680068; called by muse, mutect2, varscan2
- FANCI | c.3622del p.L1208Cfs*16 (on ENST00000310775 / NM_001376911.1; = p.L1148Cfs*16 on NM_018193.3) | Frame Shift Del (DEL) | VAF 191/687 reads (28%) | catalogued as rs1567175626; called by mutect2, pindel, varscan2
- FBXO24 | c.517C>T p.R173W (on ENST00000241071 / NM_033506.3; = p.R211W on NM_012172.5) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV53824462; called by muse, mutect2, varscan2
- FBXO41 | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs200703280, COSV54583059; called by muse, mutect2
- FCGR2A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 91/565 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV54837700; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 43/136 reads (32%) | catalogued as rs748969702; called by mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 166/589 reads (28%) | catalogued as rs766041577; called by mutect2, varscan2
- FIG4 | c.1557T>A p.N519K | Missense Mutation (SNP) | VAF 103/388 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57786332; called by muse, mutect2, varscan2
- FITM2 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV67679103; called by muse, mutect2, varscan2
- FKBP8 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs11541428, COSV55891609; called by muse, mutect2, varscan2
- FLG | c.5069A>G p.D1690G | Missense Mutation (SNP) | VAF 100/582 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64238949; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs769482947; called by mutect2, varscan2
- FMN2 | c.2963del p.P988Lfs*287 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs756221972; called by mutect2, varscan2
- FMO2 | c.291A>T p.K97N | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs749433710, COSV52947137, COSV99268875; called by muse, mutect2, varscan2
- FOXP4 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489125694, COSV57218753; called by muse, mutect2, varscan2
- FPR3 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59328759; called by muse, mutect2, varscan2
- FREM2 | c.6538C>T p.R2180C | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201190773, COSV54831178; called by muse, mutect2, varscan2
- FRMD1 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.12); catalogued as rs1236142506, COSV51960936; called by muse, mutect2, varscan2
- FRMD5 | c.518G>T p.R173M | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV68720041, COSV68720974; called by muse, mutect2, varscan2
- FTMT | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.212); catalogued as rs552079349, COSV58419472, COSV99080721; called by muse, mutect2, varscan2
- FUBP3 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60513597; called by muse, mutect2, varscan2
- FUT6 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs758628882, COSV54604914; called by muse, mutect2, varscan2
- FUT7 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs112623317, COSV55799361; called by muse, mutect2, varscan2
- FXR1 | c.344T>A p.V115D | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV59761794; called by muse, mutect2
- FYCO1 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1025398210, COSV56113995; called by muse, mutect2, varscan2
- GARRE1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.796); catalogued as rs1213911417, COSV55097820; called by muse, mutect2, varscan2
- GCDH | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55819332; called by muse, mutect2, varscan2
- GGT5 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.24); catalogued as rs567555612, COSV54069277; called by muse, mutect2, varscan2
- GJA4 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60725074; called by muse, mutect2, varscan2
- GK | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 148/473 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1321993304, COSV66736110; called by muse, mutect2, varscan2
- GLIS2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV52109811; called by muse, mutect2, varscan2
- GLUD2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1002142070, COSV60151556; called by muse, mutect2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAI3 | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63983454; called by muse, mutect2, varscan2
- GNAS | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs773471190, COSV58331036; called by muse, mutect2, varscan2
- GNLY | c.428-1G>A p.X143_splice | Splice Site (SNP) | VAF 102/401 reads (25%) | catalogued as COSV55703140; called by muse, mutect2, varscan2
- GPATCH8 | c.2413A>T p.S805C | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV59193822; called by muse, mutect2, varscan2
- GPR137B | c.117del p.Y40Tfs*2 | Frame Shift Del (DEL) | VAF 33/154 reads (21%) | catalogued as rs768730454; called by mutect2, pindel, varscan2
- GPR17 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.6); catalogued as COSV55754422, COSV99760606; called by muse, mutect2, varscan2
- GPR61 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as COSV63983450; called by muse, mutect2, varscan2
- GREB1 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52183483; called by muse, mutect2
- GRIN2D | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54377783; called by muse, mutect2, varscan2
- GRM2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV56583411; called by muse, mutect2, varscan2
- GSDMB | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 165/597 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as COSV58780153; called by muse, mutect2, varscan2
- GTF2H1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 185/543 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs763930119, COSV56376758; called by muse, mutect2, varscan2
- GYS1 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54401382; called by muse, mutect2, varscan2
- GZF1 | c.1826T>A p.I609N | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57635356; called by muse, mutect2, varscan2
- H2AC11 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as COSV60361867; called by muse, mutect2, varscan2
- HAL | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 104/371 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54117102; called by muse, mutect2, varscan2
- HEATR1 | c.2011A>G p.N671D | Missense Mutation (SNP) | VAF 113/546 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63980180; called by muse, mutect2, varscan2
- HECW1 | c.3753-2A>G p.X1251_splice | Splice Site (SNP) | VAF 78/234 reads (33%) | catalogued as COSV67825766; called by muse, mutect2, varscan2
- HELT | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1413555688, COSV58819766; called by muse, mutect2, varscan2
- HEPHL1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs570654985, COSV59890488; called by muse, mutect2, varscan2
- HGSNAT | c.133del p.R45Dfs*5 | Frame Shift Del (DEL) | VAF 62/257 reads (24%) | catalogued as rs1220771600; called by mutect2, pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 57/197 reads (29%) | catalogued as rs761272507; called by mutect2, varscan2
- HPSE2 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV65184311; called by muse, mutect2, varscan2
- HS3ST5 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 158/544 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57137346; called by muse, mutect2, varscan2
- HS3ST6 | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53533838; called by muse, mutect2, varscan2
- HSD17B11 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as rs748860213, COSV64154078; called by muse, mutect2, varscan2
- HSD17B3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs747329682, CM960844, COSV64556553; called by muse, mutect2, varscan2
- HSD3B1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778465471, COSV52489699; called by muse, mutect2, varscan2
- HTR3A | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs528104456, COSV55468629; called by muse, mutect2, varscan2
- HTR4 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 93/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792059; called by muse, mutect2, varscan2
- ID1 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.094); catalogued as COSV65888400; called by muse, mutect2, varscan2
- IFNAR1 | c.1165del p.T389Lfs*8 | Frame Shift Del (DEL) | VAF 32/119 reads (27%) | catalogued as rs755139751; called by mutect2, pindel, varscan2
- IFT52 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1047392040, COSV65974699; called by muse, mutect2, varscan2
- IL17RD | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 212/697 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV56336294; called by muse, mutect2
- IMMP2L | c.240-2A>G p.X80_splice | Splice Site (SNP) | VAF 64/270 reads (24%) | catalogued as rs1489278417, COSV59225437; called by muse, mutect2, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 44/210 reads (21%) | catalogued as rs759837481; called by mutect2, varscan2
- INSRR | c.2896+2T>C p.X966_splice | Splice Site (SNP) | VAF 79/426 reads (19%) | catalogued as COSV63871788; called by muse, mutect2, varscan2
- INTS11 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs746446373, COSV60087797; called by muse, mutect2, varscan2
- IPO13 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV64894008; called by muse, mutect2, varscan2
- ISM1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758843799, COSV52603531; called by muse, mutect2, varscan2
- ITGA7 | c.3541G>A p.A1181T (on ENST00000555728; = p.A1137T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772419744, COSV57693371; called by muse, mutect2
- IZUMO1 | c.956T>C p.I319T | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55803527; called by muse, mutect2, varscan2
- JPH2 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696636; called by muse, mutect2, varscan2
- JRK | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782182244, COSV70629616; called by muse, mutect2, varscan2
- KALRN | c.5492C>G p.P1831R (on ENST00000360013 / NM_001024660.4; = p.P134R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs751723982, COSV52253537, COSV52262990; called by muse, mutect2, varscan2
- KCNC3 | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65387059; called by muse, mutect2
- KCNH1 | c.2387C>T p.T796M (on ENST00000271751 / NM_172362.3; = p.T769M on NM_002238.4) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs770040641, COSV55074553; called by muse, mutect2, varscan2
- KCNH5 | c.2890del p.Q964Rfs*59 | Frame Shift Del (DEL) | VAF 69/254 reads (27%) | catalogued as COSV59763617; called by mutect2, pindel, varscan2
- KCNJ11 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs771797701, CM131836, COSV60594367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ14 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV53518177; called by muse, mutect2, varscan2
- KCNJ4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1471959235, COSV57856534; called by muse, mutect2, varscan2
- KCNQ4 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61272477; called by muse, mutect2, varscan2
- KCNQ5 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1328544114, COSV59654156; called by muse, mutect2, varscan2
- KIAA0319 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 68/208 reads (33%) | catalogued as rs754559914, COSV65497269; called by muse, mutect2, varscan2
- KIAA1614 | c.2638A>G p.N880D | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV62550591; called by muse, mutect2, varscan2
- KIF14 | c.4474G>T p.D1492Y | Missense Mutation (SNP) | VAF 101/646 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as COSV66260837; called by muse, mutect2, varscan2
- KIF18B | c.1642del p.I548Lfs*8 (on ENST00000593135 / NM_001265577.2; = p.I560Lfs*8 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 74/289 reads (26%) | catalogued as COSV59271648; called by mutect2, pindel, varscan2
- KIF1A | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1441846903, COSV57485576; called by muse, mutect2, varscan2
- KIF1C | c.3163C>T p.P1055S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.062); catalogued as COSV57903680; called by muse, mutect2, varscan2
- KIF20B | c.1438T>C p.C480R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV53304577; called by muse, mutect2, varscan2
- KIFC3 | c.2477-1G>T p.X826_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV65549506; called by muse, mutect2, varscan2
- KLF12 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 198/740 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.796); catalogued as rs375809451; called by muse, mutect2, varscan2
- KLHL34 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65278988; called by muse, mutect2, varscan2
- KLHL40 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs770828570, COSV55133533; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 44/77 reads (57%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLHL8 | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56747257; called by muse, mutect2, varscan2
- KLHL8 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 106/350 reads (30%) | catalogued as rs757903142, COSV56747264; called by muse, varscan2
- KMT2C | c.7513A>G p.I2505V | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV51421956; called by muse, mutect2, varscan2
- KPRP | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs373804337; called by muse, mutect2, varscan2
- KRIT1 | c.2190G>A p.M730I | Missense Mutation (SNP) | VAF 140/442 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs1195398332, COSV60667323; called by muse, mutect2, varscan2
- KRT4 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs886049646, COSV53405823; called by muse, mutect2, varscan2
- KRT8 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs537594877, COSV53176455; called by muse, mutect2, varscan2
- KRTAP26-1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770080479, COSV62128610; called by muse, varscan2
- LAMC1 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51135241; called by muse, mutect2, varscan2
- LEMD3 | c.1706C>A p.P569H | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57648321; called by muse, mutect2, varscan2
- LHCGR | c.1583T>C p.I528T | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54294732; called by muse, mutect2, varscan2
- LHFPL5 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV64177456, COSV64177490; called by muse, mutect2, varscan2
- LMNTD1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 93/335 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV51445565; called by muse, mutect2, varscan2
- LMTK2 | c.3992G>A p.R1331Q | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs767307964, COSV51990128, COSV51992876; called by muse, mutect2, varscan2
- LONRF3 | c.1303C>T p.P435S (on ENST00000371628 / NM_001031855.3; = p.P394S on NM_024778.5) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1469912220, COSV59150996; called by muse, mutect2, varscan2
- LOXL1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV56093840; called by muse, mutect2
- LOXL3 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as rs150838046; called by muse, mutect2, varscan2
- LPAR1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs267602085, COSV62687946; called by muse, mutect2, varscan2
- LPCAT2 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 17/644 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV50894677; called by muse, mutect2
- LRP12 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV52627165, COSV52628007; called by muse, mutect2, varscan2
- LRP1B | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 148/353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766132339, COSV67199923; called by muse, mutect2, varscan2
- LRP4 | c.5179G>A p.A1727T | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs914781633, COSV66134831; called by muse, mutect2, varscan2
- LRRC6 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 314/1222 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs745912588, COSV51539707; called by muse, mutect2, varscan2
- LRRC66 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755573156, COSV58632802; called by muse, mutect2, varscan2
- LRRC7 | c.1897C>T p.R633C (on ENST00000651989 / NM_001370785.2; = p.R600C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs201500873, COSV50429219; called by muse, mutect2
- LRRC8B | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58374074; called by muse, mutect2, varscan2
- LRRK2 | c.4915dup p.R1639Kfs*13 | Frame Shift Ins (INS) | VAF 29/109 reads (27%) | catalogued as rs756089224; called by mutect2, varscan2
- LYN | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70205475; called by muse, mutect2, varscan2
- LZTR1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs5761750, COSV53146208; called by muse, mutect2, varscan2
- MAN1C1 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200486051, COSV56043638; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 46/189 reads (24%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAN2A1 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV54849429; called by muse, mutect2, varscan2
- MAP2 | c.3511G>A p.V1171M | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.883); catalogued as rs757869881, COSV52285523; called by muse, mutect2, varscan2
- MAP3K2 | c.1547del p.T516Kfs*3 | Frame Shift Del (DEL) | VAF 74/421 reads (18%) | catalogued as COSV61293567; called by mutect2, pindel, varscan2
- MAP4 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 133/455 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV64237643; called by muse, mutect2, varscan2
- MAPK4 | c.1569dup p.G524Rfs*37 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | catalogued as rs1282228187; called by mutect2, varscan2
- MARCHF2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1425564961, COSV53104572; called by muse, mutect2, varscan2
- MARCHF6 | c.703_705del p.D235del | In Frame Del (DEL) | VAF 88/359 reads (25%) | catalogued as COSV56879766; called by mutect2, pindel, varscan2
- MARCO | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59053173; called by muse, mutect2, varscan2
- MARS1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV56253447; called by muse, mutect2, varscan2
- MBNL1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV56825722; called by muse, mutect2, varscan2
- MCF2L2 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV61051121; called by muse, mutect2, varscan2
- MCF2L2 | c.1858del p.R620Afs*16 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV100193332; called by mutect2, pindel, varscan2
- ME1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1465918079, COSV63838330; called by muse, mutect2, varscan2
- MEI1 | c.3104_3105del p.S1035Cfs*98 | Frame Shift Del (DEL) | VAF 50/196 reads (26%) | catalogued as rs1569321292; called by pindel, varscan2
- MELTF | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755869654, COSV56380095; called by muse, mutect2, varscan2
- MERTK | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs764637670, COSV54926788; called by muse, mutect2, varscan2
- MGA | c.4138C>T p.R1380* | Nonsense Mutation (SNP) | VAF 75/245 reads (31%) | catalogued as COSV54951082; called by muse, mutect2, varscan2
- MGA | c.7447G>T p.G2483* (on ENST00000219905 / NM_001164273.1; = p.G2274* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 63/217 reads (29%) | catalogued as COSV54951091; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKI67 | c.698dup p.N233Kfs*2 | Frame Shift Ins (INS) | VAF 100/394 reads (25%) | catalogued as rs749903408; called by mutect2, varscan2
- MMGT1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 97/302 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs782214612, COSV60002950; called by muse, mutect2, varscan2
- MMP9 | c.758T>C p.L253S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV63433904; called by muse, mutect2
- MOV10L1 | c.1209del p.V405Sfs*33 | Frame Shift Del (DEL) | VAF 43/170 reads (25%) | catalogued as rs746259938; called by mutect2, pindel, varscan2
- MPHOSPH8 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs1340344186, COSV64054846; called by muse, mutect2, varscan2
- MRE11 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60575089; called by muse, mutect2, varscan2
- MS4A1 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 139/478 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV61941883; called by muse, mutect2, varscan2
- MS4A8 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV55753626; called by muse, mutect2, varscan2
- MSMP | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 54/157 reads (34%) | catalogued as COSV100960160, COSV65239106; called by muse, mutect2, varscan2
- MST1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV56532796; called by muse, mutect2
- MTHFD1 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53699022; called by muse, mutect2, varscan2
- MTM1 | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV60334254; called by muse, mutect2, varscan2
- MTMR4 | c.60del p.K21Rfs*3 | Frame Shift Del (DEL) | VAF 47/172 reads (27%) | catalogued as rs750261859; called by mutect2, pindel, varscan2
- MXRA5 | c.5929A>G p.T1977A | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as COSV54229541; called by muse, mutect2, varscan2
- MXRA5 | c.3475C>A p.P1159T | Missense Mutation (SNP) | VAF 205/745 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV54229571; called by muse, mutect2, varscan2
- MYBL2 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53828713; called by muse, mutect2, varscan2
- MYBPH | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55141833; called by muse, mutect2
- MYCBP2 | c.1905T>C p.S635= (on ENST00000357337; = p.S673= on NM_015057.5) | Splice Region (SNP) | VAF 16/375 reads (4%) | catalogued as COSV62013439; called by muse, mutect2
- MYL2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV57406359, COSV99960858; called by muse, varscan2
- MYL9 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54072226, COSV54072819; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO18B | c.7103C>T p.P2368L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs755219230, COSV59129447; called by muse, mutect2, varscan2
- MYO1C | c.1927C>T p.R643C (on ENST00000648651 / NM_001080779.2; = p.R608C on NM_033375.5) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs771691743, COSV62998837; called by muse, mutect2, varscan2
- MYO9B | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs555189309, COSV68277950; called by muse, mutect2, varscan2
- MYPN | c.1413A>C p.E471D | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62732463; called by muse, mutect2, varscan2
- MZT2B | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56058692; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 90/332 reads (27%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAP1L2 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs760670784, COSV65172293; called by mutect2, varscan2
- NAV3 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs370224002, COSV57060374, COSV57084019; called by muse, mutect2, varscan2
- NBEA | c.7363G>A p.V2455I | Missense Mutation (SNP) | VAF 122/483 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59769784; called by muse, mutect2, varscan2
- NCF2 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62315047; called by muse, mutect2, varscan2
- NDE1 | c.726del p.T243Pfs*28 (on ENST00000577101; = p.T243Pfs*115 on NM_017668.3) | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | catalogued as rs1567656871; called by mutect2, pindel, varscan2
- NDUFS2 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 78/471 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs367801519; called by muse, mutect2, varscan2
- NEB | c.13763G>A p.R4588Q | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs575958060, COSV50890065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEMF | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs1028912182, COSV53590115; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 56/274 reads (20%) | catalogued as rs759081520; called by mutect2, varscan2
- NFKBID | c.514G>A p.D172N (on ENST00000396901; = p.D324N on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs375531604; called by muse, mutect2, varscan2
- NGEF | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50916588; called by muse, mutect2
- NIPA1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61679581; called by muse, mutect2, varscan2
- NLRC5 | c.878A>C p.Q293P | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52651922; called by muse, mutect2, varscan2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NME8 | c.507dup p.V170Sfs*5 | Frame Shift Ins (INS) | VAF 45/182 reads (25%) | catalogued as rs1167912395; called by mutect2, pindel, varscan2
- NOD1 | c.1523del p.G508Vfs*106 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs1210143813; called by mutect2, varscan2
- NOP53 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748772854, COSV55881447; called by muse, mutect2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 24/95 reads (25%) | catalogued as rs753725730; called by mutect2, varscan2
- NRSN1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1451088494, COSV65893779; called by muse, mutect2, varscan2
- NRXN1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs200202367, COSV68008273; called by muse, mutect2, varscan2
- OAS2 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs765887720, COSV60801712; called by muse, mutect2, varscan2
- OBSCN | c.17020del p.A5674Pfs*21 | Frame Shift Del (DEL) | VAF 29/175 reads (17%) | catalogued as rs757737800; called by mutect2, pindel, varscan2
- OBSL1 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs752259359, COSV54704527; called by muse, mutect2, varscan2
- OGDHL | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs575253550, COSV65100800; called by muse, mutect2, varscan2
- OR10A2 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1458067072, COSV56298960; called by muse, mutect2
- OR10K1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 173/1057 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56871222; called by muse, mutect2, varscan2
- OR2A7 | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 129/1030 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71827400; called by muse, mutect2, varscan2
- OR2G6 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs371117704; called by muse, mutect2, varscan2
- OR2T27 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs772017791, COSV61281305; called by muse, mutect2, varscan2
- OR4C6 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 124/530 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58603015; called by muse, mutect2, varscan2
- OR5M8 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59116344; called by muse, mutect2, varscan2
- OR8U1 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 147/598 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as rs1351107956, COSV100163779, COSV56414911; called by muse, varscan2
- ORM2 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV56335720; called by muse, mutect2, varscan2
- OSBPL6 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV51913618; called by muse, mutect2, varscan2
- OTOP3 | c.1695G>A p.M565I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60912705; called by muse, mutect2, varscan2
- OTOS | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56227935; called by muse, mutect2, varscan2
- OTUD7A | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as rs757148409, COSV61036342; called by muse, mutect2, varscan2
- P2RY12 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1336826072, COSV56373173, COSV56382570; called by muse, mutect2, varscan2
- PACSIN1 | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV55059250; called by muse, mutect2, varscan2
- PADI4 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV64923663; called by muse, mutect2, varscan2
- PAQR5 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV61817653; called by muse, mutect2, varscan2
- PBDC1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1029284233, COSV64895673; called by muse, mutect2, varscan2
- PCDH10 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs199719551, COSV52090301; called by muse, mutect2, varscan2
- PCDH11X | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53452865; called by muse, mutect2, varscan2
- PCDHA3 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63540052; called by muse, mutect2, varscan2
- PCDHA3 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.159); catalogued as rs1554122554, COSV63540056; called by muse, mutect2, varscan2
- PCDHB12 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 17/485 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.081); catalogued as COSV53394548; called by muse, mutect2
- PCDHB12 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV53394560; called by muse, mutect2, varscan2
- PCDHGA10 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV53919171; called by muse, mutect2, varscan2
- PCDHGA6 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs368947176; called by muse, mutect2, varscan2
- PCDHGB6 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53910872; called by muse, mutect2, varscan2
- PCNX2 | c.6082A>G p.T2028A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV50788673; called by muse, mutect2
- PDCL2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 218/697 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs775165131, COSV55259804, COSV55261512; called by muse, mutect2, varscan2
- PDGFRA | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 140/503 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57265134, COSV57266389; called by muse, mutect2, varscan2
- PDZD2 | c.308del p.G103Afs*19 | Frame Shift Del (DEL) | VAF 48/262 reads (18%) | catalogued as rs750970663; called by mutect2, pindel, varscan2
- PDZD4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1557075415, COSV51245874; called by muse, mutect2, varscan2
- PHACTR2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs868610394, COSV59852967; called by muse, mutect2, varscan2
- PHKA2 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as rs368594655, COSV66053002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIGK | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs775451686, COSV63061848; called by muse, mutect2, varscan2
- PIK3CD | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201282174; called by muse, mutect2, varscan2
- PITPNM2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54897963; called by muse, mutect2, varscan2
- PKLR | c.101-1G>T p.X34_splice | Splice Site (SNP) | VAF 13/83 reads (16%) | catalogued as CS941535, COSV61360765; called by muse, mutect2, varscan2
- PLEKHG3 | c.1796G>A p.G599D (on ENST00000394691; = p.G655D on NM_001308147.2) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs1566717103, COSV55978552; called by muse, mutect2, varscan2
- PLIN5 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60547253; called by muse, mutect2, varscan2
- PLXNA2 | c.3829C>T p.Q1277* | Nonsense Mutation (SNP) | VAF 81/430 reads (19%) | catalogued as COSV65437900; called by muse, mutect2, varscan2
- POLQ | c.7057A>C p.N2353H | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51748531; called by muse, mutect2, varscan2
- POLR3D | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV60570806; called by muse, mutect2, varscan2
- POM121 | c.2261C>T p.A754V (on ENST00000434423; = p.A489V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/540 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as rs1456605273, COSV57513291; called by muse, mutect2, varscan2
- POTEF | c.2488C>A p.P830T | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV62540431; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1405295525, COSV53451717; called by muse, mutect2
- PPFIA2 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.764); catalogued as COSV61025485; called by muse, mutect2, varscan2
- PPM1H | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs376671705; called by muse, mutect2, varscan2
- PPP1R13L | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs369362396; called by muse, mutect2, varscan2
- PPP2R2D | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV70778758, COSV70778965; called by muse, mutect2, varscan2
- PPP3R2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV62452022; called by muse, mutect2, varscan2
- PPP5C | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50139467; called by muse, mutect2, varscan2
- PRG4 | c.1772A>G p.E591G | Missense Mutation (SNP) | VAF 145/966 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV63355156; called by muse, mutect2, varscan2
- PRICKLE4 | c.111G>T p.Q37H (on ENST00000359201; = p.Q77H on NM_013397.6) | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV59254182; called by muse, mutect2, varscan2
- PRKAG2 | c.593del p.P198Rfs*56 | Frame Shift Del (DEL) | VAF 67/202 reads (33%) | catalogued as COSV55232567; called by mutect2, varscan2
- PRKCQ | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.612); catalogued as rs1314078902, COSV54107817; called by muse, mutect2, varscan2
- PRKD2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52185384; called by muse, mutect2, varscan2
- PRPF18 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 113/395 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV60724882; called by muse, mutect2, varscan2
- PRPF6 | c.2634G>T p.W878C | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53867888; called by muse, mutect2, varscan2
- PTCHD3 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs777486146, COSV71256447; called by muse, mutect2
- PTGDR | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60093391; called by muse, mutect2, varscan2
- PTP4A3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs144048289; called by muse, mutect2, varscan2
- PTPRG | c.2720T>G p.I907S | Missense Mutation (SNP) | VAF 5/148 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55634002; called by muse, mutect2
- PTPRT | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749859329, COSV61970092; called by muse, mutect2, varscan2
- PXDN | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761889364, COSV53229653; called by muse, mutect2, varscan2
- RAB3GAP1 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 123/549 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV51480267; called by muse, mutect2, varscan2
- RAB40AL | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.644); catalogued as COSV54433890; called by muse, mutect2, varscan2
- RAB40C | c.811dup p.Q271Pfs*7 | Frame Shift Ins (INS) | VAF 40/158 reads (25%) | catalogued as rs1555457247; called by mutect2, varscan2
- RADX | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65318177; called by muse, mutect2
- RARG | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58432344; called by muse, mutect2, varscan2
- RASAL1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1054772227, COSV55654759; called by muse, mutect2, varscan2
- RASL10B | c.339G>A p.T113= | Splice Region (SNP) | VAF 33/112 reads (29%) | catalogued as rs782370128; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 58/202 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RC3H2 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as COSV61799098; called by muse, mutect2, varscan2
- RET | c.1717G>A p.V573M | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs758766818, COSV60690052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 28/178 reads (16%) | catalogued as rs753959887; called by mutect2, varscan2
- RFX6 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs201446493, COSV60584103; called by muse, mutect2, varscan2
- RGS21 | c.405dup p.L136Tfs*4 | Frame Shift Ins (INS) | VAF 42/306 reads (14%) | catalogued as rs746536278; called by mutect2, pindel, varscan2
- RHOBTB1 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61958108; called by muse, mutect2, varscan2
- RNASEH2B | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60746123; called by muse, mutect2, varscan2
- RNF103 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52894173; called by muse, mutect2, varscan2
- RNF215 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as rs774285078, COSV53175673; called by muse, mutect2, varscan2
- RNF25 | c.749del p.G250Efs*29 | Frame Shift Del (DEL) | VAF 58/310 reads (19%) | catalogued as rs746813141; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 37/158 reads (23%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RORC | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs750446790, COSV59092251; called by muse, mutect2, varscan2
- RORC | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561947, COSV59092265; called by muse, mutect2, varscan2
- RP1L1 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs780579349, COSV66753308; called by muse, mutect2, varscan2
- RPS6KA2 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as rs141868317, COSV55816388; called by muse, mutect2, varscan2
- RSPH4A | c.947T>C p.M316T | Missense Mutation (SNP) | VAF 106/397 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1196326617, COSV57634115; called by muse, mutect2, varscan2
- RYR1 | c.3766-1G>T p.X1256_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV62093084; called by muse, mutect2
- RYR1 | c.7192C>T p.R2398C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as rs751654689, COSV62093089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAA1 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV62946050; called by muse, mutect2, varscan2
- SAMD11 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs758000568, COSV58986668; called by muse, mutect2, varscan2
- SCARB1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs1306998008, COSV55545248; called by muse, mutect2, varscan2
- SCARB2 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs772754806, COSV53667635; called by muse, mutect2
- SCGB1D2 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV55274214; called by muse, mutect2, varscan2
- SCNN1B | c.1228del p.R410Vfs*23 | Frame Shift Del (DEL) | VAF 84/380 reads (22%) | catalogued as rs773573081; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 220/386 reads (57%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 188/676 reads (28%) | catalogued as rs758487924; called by mutect2, varscan2
- SEPHS1 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 144/500 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV59257665; called by muse, mutect2, varscan2
- SEPTIN14 | c.427_429del p.E143del | In Frame Del (DEL) | VAF 70/314 reads (22%) | catalogued as rs1562717586; called by pindel, varscan2
- SEZ6 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375839200; called by muse, mutect2, varscan2
- SF3B3 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV56786171; called by muse, mutect2
- SH3D21 | c.1684C>T p.R562C (on ENST00000453908 / NM_001162530.2; = p.R451C on NM_024676.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as rs372370041, COSV54633815; called by muse, mutect2
- SIPA1L3 | c.3626C>T p.T1209I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55911129; called by muse, mutect2, varscan2
- SIRPB2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV63123365; called by muse, mutect2, varscan2
- SKOR1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58244764; called by muse, mutect2, varscan2
- SLC13A4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs563522177, COSV62460480, COSV62461946; called by muse, mutect2, varscan2
- SLC14A2 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 215/673 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779773763, COSV54907541; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 64/222 reads (29%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC18A1 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs141477484, COSV52347344; called by muse, mutect2, varscan2
- SLC19A1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60587570; called by muse, mutect2, varscan2
- SLC32A1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.15); catalogued as COSV54146118; called by muse, mutect2, varscan2
- SLC35B1 | c.359G>A p.R120Q (on ENST00000649906; = p.R83Q on NM_005827.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs779138081, COSV53602543; called by muse, mutect2
- SLC4A7 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | catalogued as COSV55395803; called by muse, mutect2, varscan2
- SLCO1A2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56599301; called by muse, mutect2, varscan2
- SMARCD2 | c.1491C>G p.F497L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1307287893, COSV56738492; called by muse, mutect2
- SNAI1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54863777; called by muse, mutect2
- SPHK2 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1315409607, COSV55335966; called by muse, mutect2
- SPINK5 | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs771163069, COSV56251469; called by muse, mutect2, varscan2
- SPTBN5 | c.3812G>A p.G1271D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1032235090, COSV58018527; called by muse, mutect2, varscan2
- SPTBN5 | c.2750T>C p.V917A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58018538; called by muse, varscan2
- SRRM4 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1306060661, COSV57409695; called by muse, mutect2, varscan2
- ST8SIA6 | c.144del p.A49Qfs*3 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1376602382, COSV101112163; called by mutect2, varscan2
- STAC | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 12/427 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV56208394, COSV99830589; called by muse, mutect2
- STX7 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs148495140, COSV63398513; called by muse, mutect2, varscan2
- SUCO | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55263468; called by muse, mutect2, varscan2
- SZT2 | c.5356C>T p.Q1786* (on ENST00000634258 / NM_001365999.1; = p.Q1729* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 53/174 reads (30%) | catalogued as rs1338780750, COSV65168422; called by muse, mutect2, varscan2
- TAF1L | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 199/651 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1332104754, COSV54259801; called by muse, mutect2, varscan2
- TANGO2 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs780152948, COSV59293153; called by muse, mutect2, varscan2
- TBC1D22B | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778955950, COSV65142275, COSV65142509; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCTN2 | c.1354A>T p.R452W | Missense Mutation (SNP) | VAF 129/385 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV57631998; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 44/164 reads (27%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs1404955980, COSV63969643; called by muse, mutect2, varscan2
- TENM1 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64428085, COSV64438572; called by muse, mutect2, varscan2
- TESK1 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52410623; called by muse, mutect2, varscan2
- TEX2 | c.3305T>C p.I1102T (on ENST00000583097 / NM_001288733.2; = p.I1109T on NM_018469.5) | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV51978942; called by muse, mutect2, varscan2
- TFE3 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV59946280; called by muse, mutect2, varscan2
- THRB | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.935); catalogued as COSV54979528; called by muse, mutect2, varscan2
- TIMM17B | c.212dup p.L72Pfs*56 | Frame Shift Ins (INS) | VAF 61/200 reads (31%) | catalogued as rs782500597; called by mutect2, varscan2
- TLCD1 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs868373791, COSV52043764; called by muse, mutect2, varscan2
- TLL1 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50268027; called by muse, mutect2, varscan2
- TLL1 | c.456A>T p.R152S | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV50268109; called by muse, mutect2, varscan2
- TLL1 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263487, COSV50268157; called by muse, mutect2
- TLX3 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51539472; called by muse, mutect2, varscan2
- TM4SF1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1021105863, COSV59524740; called by muse, mutect2, varscan2
- TMCO4 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs944173905, COSV53871123; called by muse, mutect2, varscan2
- TMEM163 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56105003; called by muse, mutect2, varscan2
- TMEM184A | c.1019del p.P340Rfs*15 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs747152549, COSV52472232, COSV52475858; called by mutect2, pindel, varscan2
- TMEM82 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV53816459; called by muse, mutect2, varscan2
- TMPO | c.905T>G p.F302C | Missense Mutation (SNP) | VAF 146/426 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV58461097; called by muse, mutect2, varscan2
- TMTC2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 151/476 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs200953459, COSV58262538, COSV58263260, COSV58279806; called by muse, varscan2
- TNIP1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs751538216, COSV59304380; called by muse, mutect2, varscan2
- TNK1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as COSV61170320; called by muse, mutect2, varscan2
- TNK2 | c.1522del p.Q508Sfs*3 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs754147115; called by pindel, varscan2
- TNKS | c.2813C>T p.T938M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756350259, COSV60054281; called by muse, mutect2, varscan2
- TNS2 | c.1925G>A p.R642H (on ENST00000314250 / NM_170754.4; = p.R652H on NM_015319.2) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs770327671, COSV58575953; called by muse, mutect2, varscan2
- TOMM34 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 75/485 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs758049930, COSV53839541; called by muse, mutect2, varscan2
- TOP3A | c.2264del p.G755Afs*18 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as COSV58176643; called by mutect2, pindel, varscan2
- TOPBP1 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV53434164; called by muse, mutect2
- TOR2A | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59120607; called by muse, mutect2, varscan2
- TP63 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs138832017; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TPR | c.2966A>G p.N989S | Missense Mutation (SNP) | VAF 196/1103 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747326923, COSV66600304; called by muse, mutect2, varscan2
- TRABD2A | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV59102364; called by muse, mutect2, varscan2
- TRDN | c.1050dup p.E351Rfs*7 | Frame Shift Ins (INS) | VAF 118/460 reads (26%) | catalogued as rs753514580; called by mutect2, varscan2
- TRHDE | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV53838045; called by muse, mutect2
- TRIM23 | c.275del p.N92Ifs*69 | Frame Shift Del (DEL) | VAF 47/395 reads (12%) | catalogued as rs1465925764, COSV51550889; called by mutect2, varscan2
- TRIM67 | c.2254A>G p.M752V | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV64158475; called by muse, mutect2, varscan2
- TRPA1 | c.2017del p.T673Hfs*23 | Frame Shift Del (DEL) | VAF 147/586 reads (25%) | catalogued as rs748693374; called by mutect2, pindel, varscan2
- TSC22D1 | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV71775396; called by muse, mutect2, varscan2
- TSGA10IP | c.1023G>A p.W341* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV73245245; called by muse, mutect2, varscan2
- TSPYL2 | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV60234200; called by muse, mutect2, varscan2
- TTC29 | c.150A>C p.K50N | Missense Mutation (SNP) | VAF 118/378 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV57273150; called by muse, mutect2, varscan2
- TTN | c.94204A>G p.S31402G (on ENST00000591111; = p.S23978G on NM_003319.4) | Missense Mutation (SNP) | VAF 160/674 reads (24%) | PolyPhen benign (0.266); catalogued as COSV59955865; called by muse, mutect2, varscan2
- UBE2Q1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV52724403; called by muse, mutect2, varscan2
- UBL4A | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782531758, COSV54835915; called by muse, mutect2, varscan2
- UBR4 | c.14189C>A p.A4730D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64385311; called by muse, mutect2, varscan2
- UGT1A7 | c.391del p.R131Efs*3 | Frame Shift Del (DEL) | VAF 157/807 reads (19%) | catalogued as rs66534818; called by mutect2, varscan2
- UGT2B15 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs527906107, COSV57733633; called by muse, varscan2
- UQCC1 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV62902091; called by muse, mutect2, varscan2
- USH2A | c.3525A>T p.Q1175H | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56346829; called by muse, mutect2
- USP30 | c.1290-1G>T p.X430_splice | Splice Site (SNP) | VAF 87/249 reads (35%) | catalogued as COSV57448698; called by muse, mutect2, varscan2
- USP34 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as COSV68399632; called by muse, mutect2
- USP36 | c.3022+2T>C p.X1008_splice | Splice Site (SNP) | VAF 23/70 reads (33%) | catalogued as rs1184971411, COSV61750920; called by muse, mutect2, varscan2
- USP9X | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 212/698 reads (30%) | catalogued as COSV61067345, COSV61069712; called by muse, varscan2
- UST | c.1117dup p.L373Pfs*20 | Frame Shift Ins (INS) | VAF 96/340 reads (28%) | catalogued as rs760552029; called by mutect2, varscan2
- UXS1 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as rs372716743; called by muse, mutect2, varscan2
- VANGL2 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV63604208; called by muse, mutect2, varscan2
- VCAM1 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs769528923, COSV54118516; called by muse, mutect2, varscan2
- VCX2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); catalogued as rs778441671; called by muse, mutect2
- VCX3B | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as rs1283270507; called by mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 120/495 reads (24%) | catalogued as rs756863093; called by mutect2, varscan2
- VPS13A | c.7627G>T p.E2543* | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | catalogued as COSV62426945; called by muse, mutect2, varscan2
- VPS13B | c.4100T>C p.V1367A | Missense Mutation (SNP) | VAF 175/580 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1271339267, COSV62137163; called by muse, mutect2, varscan2
- VPS13B | c.9688A>G p.R3230G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV62137095; called by muse, mutect2, varscan2
- VPS13D | c.10162C>T p.R3388* | Nonsense Mutation (SNP) | VAF 139/484 reads (29%) | catalogued as COSV50628772; called by muse, mutect2, varscan2
- VWCE | c.1466del p.P489Hfs*11 | Frame Shift Del (DEL) | VAF 35/133 reads (26%) | catalogued as rs753714493; called by mutect2, pindel, varscan2
- WARS1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59924874; called by muse, mutect2, varscan2
- WDFY3 | c.5259T>A p.F1753L | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55696638; called by muse, mutect2, varscan2
- WDPCP | c.2060T>C p.L687P | Missense Mutation (SNP) | VAF 122/540 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1559174917, COSV55415854; called by muse, mutect2, varscan2
- WDR43 | c.247del p.R83Gfs*6 | Frame Shift Del (DEL) | VAF 84/422 reads (20%) | catalogued as rs1346588778; called by mutect2, pindel, varscan2
- WDR6 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs756610808, COSV58244409; called by muse, mutect2, varscan2
- WFDC1 | c.77_79del p.L26del | In Frame Del (DEL) | VAF 36/150 reads (24%) | catalogued as rs779142020; called by pindel, varscan2
- XKR8 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.434); catalogued as COSV65834637; called by muse, mutect2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YARS2 | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61401570; called by muse, mutect2, varscan2
- ZAN | c.5953G>A p.A1985T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs1438266625, COSV61806954; called by muse, mutect2, varscan2
- ZAR1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51943348; called by muse, mutect2, varscan2
- ZBED1 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.112); catalogued as COSV58131873; called by muse, mutect2, varscan2
- ZBTB20 | c.320C>T p.T107M (on ENST00000474710 / NM_001164342.2; = p.T34M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61846206; called by muse, mutect2, varscan2
- ZC3H10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs1417301626, COSV57768433; called by muse, mutect2, varscan2
- ZFAND4 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV58897085; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs762108866; called by pindel, varscan2
- ZFHX4 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50644799; called by muse, mutect2, varscan2
- ZFP1 | c.836A>G p.Q279R | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV60032829; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 154/526 reads (29%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYM3 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 140/449 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV58736893; called by muse, mutect2, varscan2
- ZNF112 | c.493G>A p.G165S (on ENST00000337401 / NM_001083335.2; = p.G159S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as COSV61619365; called by muse, mutect2, varscan2
- ZNF23 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs757789982, COSV61840671; called by muse, mutect2, varscan2
- ZNF23 | c.298_300del p.K100del | In Frame Del (DEL) | VAF 55/214 reads (26%) | catalogued as rs368695088; called by pindel, varscan2
- ZNF33B | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 115/396 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.471); catalogued as COSV63942137; called by muse, mutect2, varscan2
- ZNF34 | c.664del p.T222Qfs*15 | Frame Shift Del (DEL) | VAF 68/222 reads (31%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF366 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs1232171149, COSV59214590; called by muse, mutect2, varscan2
- ZNF417 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 25/422 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370405550; called by muse, mutect2
- ZNF426 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV53468617; called by muse, mutect2, varscan2
- ZNF462 | c.4078C>A p.L1360I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV52933884; called by muse, mutect2, varscan2
- ZNF467 | c.67dup p.Q23Pfs*3 | Frame Shift Ins (INS) | VAF 49/198 reads (25%) | catalogued as rs764505143; called by mutect2, pindel, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF507 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748620345, COSV61330513; called by muse, mutect2, varscan2
- ZNF512 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 190/845 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV62674516; called by muse, mutect2, varscan2
- ZNF536 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs766395032, COSV62821220; called by mutect2, varscan2
- ZNF563 | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 149/520 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53370020; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF609 | c.2645del p.P882Lfs*30 | Frame Shift Del (DEL) | VAF 46/196 reads (23%) | catalogued as COSV58582904; called by mutect2, pindel, varscan2
- ZNF648 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs866620833, COSV60570187; called by muse, mutect2, varscan2
- ZNF669 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 133/675 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs774810685, COSV58537206; called by muse, mutect2, varscan2
- ZNF746 | c.985T>C p.W329R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV61406819; called by muse, mutect2, varscan2
- ZNF766 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs766094251, COSV63009205; called by muse, mutect2, varscan2
- ZSWIM3 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424094766, COSV54846063; called by muse, mutect2, varscan2
- ZSWIM3 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896620485, COSV54846073; called by muse, mutect2, varscan2
- ZXDA | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1258980117; called by muse, mutect2
- ABCC9 | c.822dup p.V275Sfs*26 | Frame Shift Ins (INS) | VAF 49/196 reads (25%) | called by mutect2, pindel, varscan2
- ABCD4 | c.881del p.F294Sfs*8 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.268del p.Q90Sfs*43 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- AMY2B | c.67_69del p.Q23del | In Frame Del (DEL) | VAF 317/1350 reads (23%) | called by pindel, varscan2
- ANKRD12 | c.2103del p.F701Lfs*11 | Frame Shift Del (DEL) | VAF 83/316 reads (26%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 22/222 reads (10%) | called by mutect2, pindel
- ASAH2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ASRGL1 | c.437del p.K146Sfs*35 | Frame Shift Del (DEL) | VAF 79/351 reads (23%) | called by mutect2, pindel, varscan2
- B3GAT1 | c.448dup p.R150Pfs*97 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- BOK | c.362dup p.K122Qfs*52 | Frame Shift Ins (INS) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- C1RL | c.1184_1190del p.P395Lfs*64 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | called by mutect2, pindel, varscan2
- C1orf112 | c.1756_1759del p.C586Ifs*19 | Frame Shift Del (DEL) | VAF 110/752 reads (15%) | called by mutect2, pindel, varscan2
- CCDC178 | c.1617del p.K539Nfs*32 | Frame Shift Del (DEL) | VAF 64/252 reads (25%) | called by mutect2, pindel, varscan2
- CDKL3 | c.381del p.K127Nfs*6 | Frame Shift Del (DEL) | VAF 62/207 reads (30%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6642del p.V2215Wfs*26 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 79/294 reads (27%) | called by mutect2, varscan2
- CHAT | c.1441del p.R481Gfs*15 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 67/227 reads (30%) | called by mutect2, pindel, varscan2
- CHD5 | c.2580del p.F860Lfs*4 | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | called by mutect2, pindel, varscan2
- CHMP4B | c.67del p.Q23Rfs*14 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- COL8A1 | c.1650del p.G551Vfs*23 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.5571_5572del p.R1857Sfs*10 | Frame Shift Del (DEL) | VAF 94/389 reads (24%) | called by pindel, varscan2
- CYP21A2 | c.1096dup p.H366Pfs*16 | Frame Shift Ins (INS) | VAF 18/135 reads (13%) | called by mutect2, varscan2
- DDO | c.408del p.F136Lfs*4 | Frame Shift Del (DEL) | VAF 74/247 reads (30%) | called by mutect2, pindel, varscan2
- DHX38 | c.2088del p.F696Lfs*33 | Frame Shift Del (DEL) | VAF 102/374 reads (27%) | called by mutect2, pindel, varscan2
- DST | c.8700del p.A2901Qfs*3 | Frame Shift Del (DEL) | VAF 51/233 reads (22%) | called by mutect2, pindel, varscan2
- EHHADH | c.305del p.G102Dfs*2 | Frame Shift Del (DEL) | VAF 78/289 reads (27%) | called by mutect2, pindel, varscan2
- EML2 | c.497dup p.F167Lfs*5 | Frame Shift Ins (INS) | VAF 78/308 reads (25%) | called by mutect2, pindel, varscan2
- EP300 | c.4640del p.N1547Mfs*17 | Frame Shift Del (DEL) | VAF 45/175 reads (26%) | called by mutect2, pindel, varscan2
- EPRS1 | c.387del p.G130Efs*9 | Frame Shift Del (DEL) | VAF 55/346 reads (16%) | called by mutect2, pindel, varscan2
- FAM71A | c.106dup p.E36Gfs*12 | Frame Shift Ins (INS) | VAF 53/307 reads (17%) | called by mutect2, pindel, varscan2
- FAT4 | c.750del p.F250Lfs*91 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- FBXO30 | c.1990del p.R664Gfs*12 | Frame Shift Del (DEL) | VAF 161/637 reads (25%) | called by mutect2, pindel, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 64/269 reads (24%) | called by mutect2, pindel, varscan2
- FUBP1 | c.1192del p.T398Pfs*2 | Frame Shift Del (DEL) | VAF 110/507 reads (22%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1008del p.T337Pfs*25 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by pindel, varscan2
- GCC2 | c.2106del p.K702Nfs*3 | Frame Shift Del (DEL) | VAF 55/222 reads (25%) | called by mutect2, varscan2
- GPR155 | c.1385-2A>G p.X462_splice | Splice Site (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2
- GREM2 | c.334_336del p.K112del | In Frame Del (DEL) | VAF 13/116 reads (11%) | called by pindel, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | called by mutect2, varscan2
- HIP1R | c.1032del p.N345Mfs*4 | Frame Shift Del (DEL) | VAF 32/129 reads (25%) | called by mutect2, pindel, varscan2
- IL18R1 | c.996_998del p.I333del | In Frame Del (DEL) | VAF 270/1217 reads (22%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- ISG20L2 | c.657del p.C220Afs*19 | Frame Shift Del (DEL) | VAF 59/362 reads (16%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.2729del p.P910Qfs*15 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | called by mutect2, pindel, varscan2
- KLK11 | c.556del p.Q186Sfs*94 (on ENST00000594768 / NM_144947.3; = p.Q154Sfs*94 on NM_006853.3) | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.531del p.C178Afs*203 | Frame Shift Del (DEL) | VAF 73/597 reads (12%) | called by mutect2, pindel, varscan2
- LBHD1 | c.292_293del p.S98Wfs*8 (on ENST00000431002 / NM_001367940.1; = p.S72Wfs*8 on NM_024099.3) | Frame Shift Del (DEL) | VAF 126/470 reads (27%) | called by pindel, varscan2
- LRRC75A | c.521del p.P174Qfs*12 (on ENST00000470794 / NM_001113567.3; = p.R136Dfs*171 on NM_207387.4) | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.437_438dup p.K147Gfs*54 | Frame Shift Ins (INS) | VAF 37/152 reads (24%) | called by mutect2, varscan2
- MARK2 | c.1888del p.A630Pfs*27 (on ENST00000402010 / NM_001039469.2; = p.A575Pfs*18 on NM_004954.5) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- MICAL2 | c.3332del p.P1111Qfs*20 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- MLF1 | c.460del p.M154Wfs*34 | Frame Shift Del (DEL) | VAF 47/168 reads (28%) | called by mutect2, pindel, varscan2
- MYO1F | c.1364del p.P455Qfs*4 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, varscan2
- MYO3A | c.3909dup p.E1304Rfs*26 | Frame Shift Ins (INS) | VAF 89/260 reads (34%) | called by mutect2, pindel, varscan2
- NCKAP5L | c.399del p.S134Pfs*2 | Frame Shift Del (DEL) | VAF 47/308 reads (15%) | called by mutect2, pindel, varscan2
- NPR3 | c.1314dup p.E439Rfs*5 | Frame Shift Ins (INS) | VAF 142/611 reads (23%) | called by mutect2, pindel, varscan2
- PHF24 | c.703dup p.D235Gfs*3 | Frame Shift Ins (INS) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- PKMYT1 | c.1369del p.R457Gfs*12 | Frame Shift Del (DEL) | VAF 37/131 reads (28%) | called by mutect2, pindel, varscan2
- PLD2 | c.1072_1074del p.E358del | In Frame Del (DEL) | VAF 68/282 reads (24%) | called by pindel, varscan2
- POLR2A | c.472del p.E158Rfs*18 | Frame Shift Del (DEL) | VAF 97/389 reads (25%) | called by mutect2, pindel, varscan2
- POLR2B | c.2463del p.G822Dfs*19 | Frame Shift Del (DEL) | VAF 65/397 reads (16%) | called by mutect2, pindel, varscan2
- POU2F2 | c.187-3del | Splice Region (DEL) | VAF 18/109 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 22/792 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); called by muse, mutect2
- PRPF3 | c.497del p.P166Lfs*31 | Frame Shift Del (DEL) | VAF 128/754 reads (17%) | called by mutect2, pindel, varscan2
- PTPRB | c.1838_1839del p.L613Qfs*44 | Frame Shift Del (DEL) | VAF 60/295 reads (20%) | called by pindel, varscan2
- RBL2 | c.387del p.F129Lfs*4 | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | called by mutect2, pindel, varscan2
- RCBTB2 | c.298del p.I100* | Frame Shift Del (DEL) | VAF 72/273 reads (26%) | called by mutect2, pindel, varscan2
- RIT2 | c.480del p.F160Lfs*18 | Frame Shift Del (DEL) | VAF 84/385 reads (22%) | called by mutect2, pindel, varscan2
- RNMT | c.1416dup p.E473* | Frame Shift Ins (INS) | VAF 147/600 reads (25%) | called by mutect2, pindel, varscan2
- RTN2 | c.1222dup p.D408Gfs*112 | Frame Shift Ins (INS) | VAF 27/119 reads (23%) | called by mutect2, pindel, varscan2
- RYR1 | c.8710del p.L2904Cfs*24 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- SCAF4 | c.359del p.N120Mfs*25 | Frame Shift Del (DEL) | VAF 100/384 reads (26%) | called by mutect2, pindel, varscan2
- SCN4A | c.2919dup p.E974Rfs*5 | Frame Shift Ins (INS) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- SEMG1 | c.1269del p.G424Afs*14 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | called by mutect2, pindel, varscan2
- SH3PXD2A | c.1584del p.S529Afs*43 (on ENST00000369774 / NM_001365079.1; = p.S501Afs*43 on NM_014631.2) | Frame Shift Del (DEL) | VAF 51/189 reads (27%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.253del p.L85Cfs*27 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- SLC9A5 | c.1340dup p.L447Ffs*16 | Frame Shift Ins (INS) | VAF 52/186 reads (28%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.2989dup p.M997Nfs*21 | Frame Shift Ins (INS) | VAF 108/458 reads (24%) | called by mutect2, varscan2
- SMARCAD1 | c.1040dup p.N347Kfs*4 | Frame Shift Ins (INS) | VAF 42/198 reads (21%) | called by mutect2, varscan2
- SNRNP200 | c.2134del p.I712Sfs*32 | Frame Shift Del (DEL) | VAF 120/576 reads (21%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.368del p.P123Lfs*21 | Frame Shift Del (DEL) | VAF 52/217 reads (24%) | called by mutect2, varscan2
- SYT14 | c.86del p.L29Cfs*10 | Frame Shift Del (DEL) | VAF 254/1456 reads (17%) | called by mutect2, pindel, varscan2
- SZT2 | c.5829del p.P1944Rfs*13 (on ENST00000634258 / NM_001365999.1; = p.P1887Rfs*13 on NM_015284.4) | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- TFAP2E | c.718dup p.E240Gfs*77 | Frame Shift Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- TP53RK | c.714del p.K238Nfs*2 | Frame Shift Del (DEL) | VAF 146/472 reads (31%) | called by mutect2, varscan2
- TPRKB | c.254dup p.N86Kfs*2 | Frame Shift Ins (INS) | VAF 169/769 reads (22%) | called by mutect2, pindel, varscan2
- TRA2A | c.793_795del p.Y265del | In Frame Del (DEL) | VAF 82/336 reads (24%) | called by pindel, varscan2
- TRBV4-2 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 81/417 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TRRAP | c.5533del p.H1845Tfs*18 (on ENST00000359863 / NM_001244580.1; = p.H1827Tfs*18 on NM_003496.3) | Frame Shift Del (DEL) | VAF 49/153 reads (32%) | called by mutect2, pindel, varscan2
- UPK1A | c.240del p.F80Lfs*48 | Frame Shift Del (DEL) | VAF 79/342 reads (23%) | called by mutect2, pindel, varscan2
- USH2A | c.15286del p.E5096Kfs*6 | Frame Shift Del (DEL) | VAF 71/429 reads (17%) | called by mutect2, pindel, varscan2
- VWA2 | c.1430del p.G477Vfs*2 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- ZHX2 | c.1591dup p.Q531Pfs*12 | Frame Shift Ins (INS) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- ZNF354B | c.413del p.N138Mfs*6 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | called by mutect2, pindel, varscan2
- ZNF831 | c.2134dup p.E712Gfs*10 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2166G>A p.R722= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV54026651; called by muse, mutect2
- ABCB7 | c.1947T>C p.G649= (on ENST00000373394 / NM_001271696.3; = p.G650= on NM_004299.6) | Silent (SNP) | VAF 97/359 reads (27%) | catalogued as COSV53718830; called by muse, mutect2, varscan2
- ADAMTS8 | c.1170C>T p.H390= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs774085001, COSV57292371; called by muse, mutect2, varscan2
- ADGRL1 | c.624C>T p.P208= (on ENST00000340736 / NM_001008701.3; = p.P203= on NM_014921.5) | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs776983672, COSV61564087; called by muse, mutect2, varscan2
- AJAP1 | c.1011G>A p.S337= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs532761720, COSV65449974; called by muse, mutect2, varscan2
- AL031777.2 | c.108C>G p.R36= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV61911732; called by muse, mutect2, varscan2
- ANKS1B | c.912A>G p.Q304= | Silent (SNP) | VAF 91/513 reads (18%) | catalogued as COSV61341940; called by muse, mutect2, varscan2
- AP2A1 | c.2490C>T p.C830= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs771204705, COSV100571088, COSV58241058; called by muse, mutect2, varscan2
- ARFGEF1 | c.2331C>T p.F777= | Silent (SNP) | VAF 93/313 reads (30%) | catalogued as rs201018737, COSV51604095; called by muse, mutect2, varscan2
- ARHGAP4 | c.2445G>A p.L815= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1191932637, COSV61685949; called by muse, mutect2, varscan2
- ARHGEF10 | c.2118C>T p.D706= (on ENST00000398564; = p.D681= on NM_014629.4) | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as rs537649967, COSV50644503; called by muse, mutect2, varscan2
- ATOH1 | c.54C>T p.D18= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs776252021, COSV60037652; called by muse, mutect2, varscan2
- ATP2A3 | c.2709G>A p.V903= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as rs1203392933, COSV59227602; called by muse, mutect2, varscan2
- BACH1 | c.2127T>C p.A709= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV54517959; called by muse, mutect2, varscan2
- BTN1A1 | c.237C>T p.D79= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV55067053; called by muse, mutect2
- C12orf56 | c.234C>T p.D78= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV61486063; called by muse, mutect2
- CACNA1A | c.1395C>T p.N465= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV64193455; called by muse, mutect2
- CALCOCO1 | c.1578C>T p.A526= | Silent (SNP) | VAF 58/205 reads (28%) | catalogued as rs553694643, COSV50412573; called by muse, mutect2, varscan2
- CASP3 | c.72C>T p.S24= | Silent (SNP) | VAF 116/451 reads (26%) | catalogued as rs35566035; called by muse, mutect2, varscan2
- CBFA2T3 | c.291C>T p.F97= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV51924981; called by muse, mutect2, varscan2
- CCDC33 | c.162C>T p.S54= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as rs368462763; called by muse, mutect2, varscan2
- CCDC82 | c.315C>T p.N105= | Silent (SNP) | VAF 256/869 reads (29%) | catalogued as rs774545821, COSV53592719; called by muse, mutect2, varscan2
- CD38 | c.690G>A p.L230= | Silent (SNP) | VAF 29/1038 reads (3%) | catalogued as COSV56889102; called by muse, mutect2
- CDK12 | c.1461C>T p.S487= | Silent (SNP) | VAF 16/293 reads (5%) | catalogued as rs1334093327, COSV101420551, COSV70999887; called by muse, mutect2
- CENPA | c.261A>G p.Q87= | Silent (SNP) | VAF 130/489 reads (27%) | catalogued as COSV51982473; called by muse, mutect2, varscan2
- CMTR2 | c.1659A>G p.E553= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs764133703, COSV57602975; called by muse, mutect2, varscan2
- CNR2 | c.894C>T p.I298= | Silent (SNP) | VAF 55/215 reads (26%) | catalogued as COSV65692605, COSV65693705; called by muse, mutect2, varscan2
- CNTNAP2 | c.2235C>T p.C745= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs773833579, COSV62152409; called by muse, mutect2, varscan2
- COL19A1 | c.2007G>A p.K669= | Silent (SNP) | VAF 62/220 reads (28%) | catalogued as COSV59568845; called by muse, mutect2, varscan2
- COL26A1 | c.237G>A p.V79= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV58122383; called by muse, mutect2, varscan2
- COL2A1 | c.1431C>T p.G477= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV104398494, COSV61529100, COSV61532706; called by muse, mutect2, varscan2
- COL4A2 | c.3537C>T p.G1179= | Silent (SNP) | VAF 49/158 reads (31%) | catalogued as COSV64626475; called by muse, mutect2, varscan2
- COL5A2 | c.1896A>G p.A632= | Silent (SNP) | VAF 74/386 reads (19%) | catalogued as COSV66408315; called by muse, mutect2, varscan2
- CRB1 | c.2400C>T p.I800= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV66329185; called by muse, mutect2
- CRB1 | c.3618C>T p.Y1206= | Silent (SNP) | VAF 44/247 reads (18%) | catalogued as COSV66329189; called by muse, mutect2, varscan2
177 further variants in this file (0 protein-altering or splice-affecting, 162 silent, 15 other) are not listed here.
